CPTAC case C3N-04293 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c7b9cd75-21c0-4c73-b81c-addbf9692409

Demographics
Sex at birth: male; Race: white; Year of birth: 1942; Vital status: Dead; Days to death: 245 days; Year of death: 2019; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 75.7 years (27,654 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: M1a; AJCC pathologic T: T4b; AJCC pathologic N: N2b; AJCC pathologic M: M1a; AJCC pathologic stage: Stage IV; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 245 days; Progression or recurrence: no; Days to last follow up: 209 days; Clark level: V; Tumor focality: Multifocal; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >4.0 mm; Greatest tumor dimension: 4 cm; Lymph node involvement: Positive; Lymph nodes positive: 2; Margin status: Uninvolved; Perineural invasion present: No.

Follow-up (1 entry)
- Days to follow up: 209 days; Disease response: With Tumor; Karnofsky performance status: 0; ECOG performance status: 5.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Cigarettes per day: 3; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-04293-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -13 days; Initial weight: 141 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-04293-22: Section location: Lymph node; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3N-04293-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -14 days; Method of sample procurement: Blood Draw.
